TCGA case TCGA-D9-A148 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Breast; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fed23055-1600-4128-8d73-e1aa902a9d1d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 40 years; Vital status: Alive.

Diagnoses (6)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C50.9; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: Progression; Prior treatment: Yes; Days to last follow up: 4,609 days (12.6 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Timepoint category: Prior to Procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 40.5 years (14,805 days); Year of diagnosis: 1999; AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: N3; AJCC pathologic M: M1b; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ipilimumab; Initial disease status: Recurrent Disease; Days to treatment start: 4,426 days (12.1 years); Days to treatment end: 4,496 days (12.3 years); Number of cycles: 4; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 4,468 days (12.2 years); Days to treatment end: 4,473 days (12.2 years); Treatment dose: 2,000 cGy; Number of fractions: 5; Treatment anatomic sites: Distant Site.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Recorded as not given: Radiation Therapy, NOS.
4. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Thorax, NOS. Age at diagnosis: 52.3 years (19,092 days); Days to diagnosis: 4,287 days (11.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.
5. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 52.3 years (19,092 days); Days to diagnosis: 4,287 days (11.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 4,540 days (12.4 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
6. Metastasis of diagnosis 2 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 52.5 years (19,169 days); Days to diagnosis: 4,364 days (11.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS, for progressive disease.

Follow-up (5 entries)
- Day 4,287 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 4,287 days (11.7 years).
- Day 4,287 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 4,287 days (11.7 years).
- Day 4,364 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 4,364 days (11.9 years).
- Days to follow up: 4,511 days (12.4 years); Disease response: With Tumor.
- Days to follow up: 4,609 days (12.6 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 84 kg; Height: 179 cm; BMI: 26.2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D9-A148-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D9-A148-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 230 mg.
  Slide TCGA-D9-A148-06A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 14; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-D9-A148-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Primary melanoma tumor ulceration: No; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; History neoadjuvant treatment: Yes; Ifn treatment 90 days prior to resection: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk.
- Prior systemic therapy types: History neoadjuvant treatment type: Immunotherapy/Vaccine.
- Drug treatment: Therapy regimen: Recurrence.
- Drug treatment, Route of administrations: Route of administration: IV.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Patient received immunotherapy/vaccine for the TCGA tumor.
- Neoadjuvant therapy: systemic treatment.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 4,609 days; disease-specific survival: no event (censored), 4,609 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 4,287 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D9-A148-06A-11D-A192-01): tumor purity 0.73, ploidy 3.69, whole-genome doublings 1.
